Somatic mutation profile of tumor specimen TARGET-50-PAJMVC-01A (aliquot TARGET-50-PAJMVC-01A-01D) from TARGET case TARGET-50-PAJMVC, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.2 years (1,548 days).
Specimen TARGET-50-PAJMVC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97a55a3f-9857-4ad2-bb1e-e2142f414657.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJMVC-10A (Blood Derived Normal), aliquot TARGET-50-PAJMVC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06fd1188-2dec-493e-b9d2-d1b5e710d3e0

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 156/328 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 38/40 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs375338359, CM098494, COSV52690857, COSV52980226, COSV53438718; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD6 | c.532T>A p.Y178N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV55909225; called by muse, mutect2, varscan2
- BABAM2 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 114/254 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV59626641; called by muse, mutect2, varscan2
- CDH8 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 197/426 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs762249948, COSV54865707, COSV54878044; called by muse, mutect2, varscan2
- COL19A1 | c.782C>A p.S261* | Nonsense Mutation (SNP) | VAF 90/409 reads (22%) | catalogued as COSV59568641; called by muse, mutect2, varscan2
- CSTF1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 128/266 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.305); catalogued as COSV53859246; called by muse, mutect2, varscan2
- FASTKD1 | c.2257C>G p.Q753E | Missense Mutation (SNP) | VAF 263/560 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV71624418; called by muse, mutect2, varscan2
- IL20RA | c.835G>C p.V279L | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV57356930; called by muse, mutect2
- NOS1 | c.1802G>A p.R601H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57615513; called by muse, mutect2, varscan2
- OR4C46 | c.773G>T p.R258I | Missense Mutation (SNP) | VAF 191/411 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV60220164; called by muse, mutect2, varscan2
- PCDH15 | c.5530A>T p.T1844S | Missense Mutation (SNP) | VAF 345/678 reads (51%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV57340408; called by muse, mutect2, varscan2
- PGK2 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59164450; called by muse, mutect2, varscan2
- PLEKHS1 | c.44T>A p.V15D (on ENST00000369310 / NM_182601.1; = p.V21D on NM_024889.5) | Missense Mutation (SNP) | VAF 159/389 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771767388; called by muse, mutect2, varscan2
- SRL | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.915); catalogued as rs746174970, COSV68423869; called by muse, mutect2, varscan2
- UBA2 | c.1099A>T p.S367C | Missense Mutation (SNP) | VAF 58/460 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55831342; called by muse, mutect2, varscan2
- ZNF91 | c.1612A>T p.I538L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as rs1164680758, COSV56087007; called by muse, varscan2
- ZNF91 | c.1540G>T p.G514* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as COSV56087026; called by muse, varscan2
- BCOR | c.4340_4343del p.R1447Lfs*36 (on ENST00000378444 / NM_001123385.2; = p.R1413Lfs*36 on NM_017745.6) | Frame Shift Del (DEL) | VAF 64/70 reads (91%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NLRP9 | c.944G>C p.S315T | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GJC1 | c.711T>A p.G237= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- MIPEP | c.1536C>T p.H512= | Silent (SNP) | VAF 61/155 reads (39%) | catalogued as rs560610362, COSV66301148; called by muse, mutect2, varscan2
- PAPPA | c.711G>T p.V237= | Silent (SNP) | VAF 27/41 reads (66%) | called by muse, mutect2, varscan2
- ZNF91 | c.1611G>A p.K537= | Silent (SNP) | VAF 44/94 reads (47%) | called by muse, varscan2
